CGCI case BLGSP-71-27-00427 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3cb234c8-c4d8-48c1-84d6-a5a7cc30b066

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 29 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 29.6 years (10,823 days); Year of diagnosis: 2016; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 338 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Other; Sites of involvement: Anus, NOS.
   Pathology details: Bone marrow malignant cells: No.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: DA-EPOCH; Days to treatment start: 23 days; Days to treatment end: 84 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 23 days; Days to treatment end: 84 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 338 days; Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2 loss (FISH): Abnormal, NOS.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6: Normal.
- CCND1 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD5 (IHC): Negative.
- IRF4 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC gain (FISH): Abnormal, NOS.
- MYC translocation (FISH): Negative.
- Test (IHC): Negative; Specialized molecular test: EBER.
- Test (IHC): Negative; Specialized molecular test: TdT.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 131 [Blood test normal range upper: 250].

Other clinical attributes
- Day 0: Weight: 93.4 kg; Height: 167.4 cm; BMI: 33.3.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-27-00427-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-27-00427-01A-01-S1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-27-00427-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Extranodal involvment other: anus; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 131; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: MUM1.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: Cyclin D1.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: TdT.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: Eber.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality results: Gain.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2; Genetic abnormality results: Loss.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: DA-EPOCH + Rituxumab; Pharma adjuvant cycles count: 3.
